Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6824, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6824-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: M

Material: **Lesion resection – larynx**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Tumour of the larynx (Clinically: circular proliferation covering 2/3 of the front part of both vocal folds, both laryngeal vestibules and anterior commissure.)**

Examination performed on:

Macroscopic description:

Surgical specimen sized 9.5 x 5 x 5.5 cm containing the larynx, hyoid bone and a 1 cm length of the trachea.

Tumour sized 3.8 x 2.1 x 2.6 cm in the supraglottal and subglottal region infiltrating into the infrahyoid region.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum G2.

The tumour spreads over all levels of the larynx, thyroid cartilage and an adjacent small part of the thyroid.

Surgical incision lines free of neoplastic proliferation. Minimal margin (front): below 0.1 cm.

Histopathological diagnosis:

Carcinoma planoepitheliale keratodes invasivum laryngis. Invasive keratinized squamous carcinoma of the larynx. G2, pT4a.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 628f44b0-6651-4eb9-b3b0-8dbf35fe61a8 (TCGA-D6-6824.CD34C4DF-AF91-44C9-8DF1-494EBCAAD335.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).